HCMI case HCM-BROD-0871-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33165ed4-5f38-4566-8d0d-82e2a6d2743f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1950; Vital status: Alive.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.9; Tissue or organ of origin: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 60.7 years (22,167 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T0; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Metastasis of the uterus (histology not recorded by GDC). ICD-10 code: C79.8; Site of resection or biopsy: Pelvis, NOS; Age at diagnosis: 69.0 years (25,208 days); Days to diagnosis: 3,041 days (8.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Anastrozole + Dacarbazine + Docetaxel + Trabectedin; Treatment intent type: Maintenance Therapy; Days to treatment start: 58 days; Days to treatment end: 2,948 days (8.1 years); Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 3,065 days (8.4 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 18.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0871-C49-06B: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-0871-C49-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0871-C49-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0871-C49-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0871-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 18.
